Somatic mutation profile of tumor specimen C3L-06205-02 (aliquot CPT0456790005) from CPTAC case C3L-06205, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 45.6 years (16,641 days).
Specimen C3L-06205-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 643157c5-b3df-49ec-a438-8748d1a61d49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06205-32 (Blood Derived Normal), aliquot CPT0456900003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5581a6ad-87cc-434c-988f-06f7db593930

The open-access MAF lists 543 somatic variants for this specimen: 348 protein-altering or splice-affecting, 168 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 311, Silent 168, Nonsense Mutation 24, Intron 17, Splice Region 9, 5'UTR 3, Splice Site 2, 3'UTR 2, 3'Flank 2, 5'Flank 2, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 152/277 reads (55%) | catalogued as rs587779780, CD042580, CM920031, COSV57322404; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/152 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, varscan2
- CNOT9 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 126/295 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs267599211, COSV55298957; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DDX3X | c.133C>T p.R45* (on ENST00000399959; = p.R46* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 28/42 reads (67%) | catalogued as rs1569234653, CM158020, COSV101302319; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC27A5 | c.1661C>T p.T554I | Missense Mutation (SNP) | VAF 101/242 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202081924, COSV54017957; called by muse, mutect2, varscan2
- AAMP | c.719G>A p.R240K | Missense Mutation (SNP) | VAF 96/255 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.095); catalogued as COSV50307916; called by muse, mutect2, varscan2
- ACAN | c.753G>A p.M251I | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV61360071; called by muse, mutect2, varscan2
- ADAMDEC1 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 116/324 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.072); catalogued as rs141146768; called by muse, mutect2, varscan2
- ADGRB3 | c.3154G>A p.G1052R | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53258675; called by muse, mutect2, varscan2
- ADH1A | c.1076G>A p.G359E | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52926019; called by muse, mutect2, varscan2
- ADH7 | c.367C>T p.L123F | Missense Mutation (SNP) | VAF 112/276 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.045); catalogued as rs758704409; called by muse, mutect2, varscan2
- AGPAT1 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 82/1128 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1472994637; called by muse, mutect2
- AMER3 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 149/503 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1450089428; called by muse, mutect2, varscan2
- ANKRD24 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 185/520 reads (36%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.525); catalogued as rs778777281; called by muse, mutect2, varscan2
- ANKRD30A | c.1900G>A p.E634K (on ENST00000611781; = p.E578K on NM_052997.2) | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.145); catalogued as rs1006787924; called by muse, mutect2, varscan2
- AP3B1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1292281210; called by muse, mutect2, varscan2
- APOBEC2 | c.640T>C p.Y214H | Missense Mutation (SNP) | VAF 203/391 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1213344921; called by muse, mutect2, varscan2
- ARAP2 | c.1924C>T p.R642* | Nonsense Mutation (SNP) | VAF 43/105 reads (41%) | catalogued as rs772066488; called by muse, mutect2, varscan2
- ARHGAP45 | c.581G>A p.S194N | Missense Mutation (SNP) | VAF 91/268 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.073); catalogued as COSV57431852; called by muse, mutect2, varscan2
- ARMC3 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 42/111 reads (38%) | catalogued as rs78062147; called by muse, mutect2, varscan2
- ASTN1 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 216/452 reads (48%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); catalogued as COSV99922842; called by muse, mutect2, varscan2
- ASXL3 | c.5362G>A p.G1788S | Missense Mutation (SNP) | VAF 147/374 reads (39%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.214); catalogued as COSV99324130; called by muse, mutect2, varscan2
- ATG2B | c.2710C>T p.R904C | Missense Mutation (SNP) | VAF 65/187 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1430305690, COSV63421484; called by muse, mutect2, varscan2
- CALHM3 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 185/449 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs1388267231; called by muse, mutect2, varscan2
- CAMSAP3 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 138/412 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as rs780265160; called by muse, mutect2, varscan2
- CAPN9 | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 121/355 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55233268; called by muse, mutect2, varscan2
- CCDC150 | c.1030-1G>T p.X344_splice | Splice Site (SNP) | VAF 58/163 reads (36%) | catalogued as COSV99776968; called by muse, mutect2, varscan2
- CCDC150 | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1338503025; called by muse, mutect2, varscan2
- CCNY | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 99/326 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs745753554, COSV99590888; called by muse, mutect2, varscan2
- CD177 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 109/410 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.331); catalogued as COSV65122943; called by muse, mutect2
- CD209 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 103/328 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.291); catalogued as COSV99214100; called by muse, mutect2, varscan2
- CDH13 | c.1628C>T p.S543F | Missense Mutation (SNP) | VAF 106/327 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99224023; called by muse, mutect2, varscan2
- CHIA | c.481G>A p.E161K (on ENST00000343320; = p.E53K on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 101/254 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs866842630, COSV58476663; called by muse, mutect2, varscan2
- CNGB3 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 62/211 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as rs905033514, COSV60686519; called by muse, mutect2, varscan2
- CNTNAP2 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 63/270 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.359); catalogued as COSV62147964; called by muse, mutect2, varscan2
- COL27A1 | c.2456C>T p.P819L | Missense Mutation (SNP) | VAF 107/362 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV61930075; called by muse, varscan2
- COL8A1 | c.1327C>T p.L443F | Missense Mutation (SNP) | VAF 156/469 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.36); catalogued as rs1256624821; called by muse, mutect2, varscan2
- CPQ | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 127/354 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV55137122; called by muse, mutect2, varscan2
- CSF3R | c.666G>A p.M222I | Missense Mutation (SNP) | VAF 93/261 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.361); catalogued as COSV58963771; called by muse, mutect2, varscan2
- CSMD2 | c.2785C>T p.Q929* | Nonsense Mutation (SNP) | VAF 93/288 reads (32%) | catalogued as COSV53957024; called by muse, mutect2, varscan2
- CT47B1 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 184/240 reads (77%) | SIFT tolerated (0.35); PolyPhen benign (0.151); catalogued as rs755635888; called by muse, mutect2, varscan2
- CTAGE6 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 74/682 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.283); catalogued as rs1321949143; called by muse, varscan2
- CTAGE9 | c.2219G>A p.R740K | Missense Mutation (SNP) | VAF 121/520 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.615); catalogued as COSV99040524; called by muse, mutect2, varscan2
- CTSG | c.716G>A p.R239K | Missense Mutation (SNP) | VAF 132/368 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53536964; called by muse, mutect2, varscan2
- CXCR4 | c.769A>T p.I257F | Missense Mutation (SNP) | VAF 137/415 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs749571357; called by mutect2, varscan2
- DDX11 | c.2899G>A p.G967R | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as rs1287274938; called by muse, mutect2, varscan2
- DDX31 | c.2366C>T p.S789L | Missense Mutation (SNP) | VAF 130/363 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760979836, COSV55039016; called by muse, mutect2, varscan2
- DGKQ | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 121/289 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.033); catalogued as rs1303417746; called by muse, mutect2, varscan2
- DHDH | c.478C>T p.H160Y | Missense Mutation (SNP) | VAF 185/494 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV55481629; called by muse, mutect2, varscan2
- DMRTB1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 161/487 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as rs775426210, COSV65112864; called by muse, mutect2, varscan2
- ECM2 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 211/560 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1298397170; called by muse, varscan2
- ENOX1 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 122/368 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV54896195; called by muse, mutect2, varscan2
- F13B | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 91/206 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV66373664; called by muse, mutect2, varscan2
- FAM111A | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 122/332 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs763862771, COSV64655389; called by muse, mutect2, varscan2
- FAM9B | c.281G>A p.R94K | Missense Mutation (SNP) | VAF 60/82 reads (73%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.694); catalogued as rs886947038; called by muse, mutect2, varscan2
- FER1L6 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 149/405 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67548489; called by muse, mutect2, varscan2
- FILIP1 | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 82/237 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs776455963, COSV52725973; called by muse, mutect2, varscan2
- FLG | c.11105G>A p.G3702E | Missense Mutation (SNP) | VAF 259/661 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs1274174043, COSV64253384; called by muse, mutect2, varscan2
- FMR1NB | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 108/145 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV65073168; called by muse, mutect2, varscan2
- GALP | c.315G>A p.M105I | Missense Mutation (SNP) | VAF 123/313 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs867751771, COSV61999251; called by muse, mutect2, varscan2
- GAPVD1 | c.4123C>T p.P1375S (on ENST00000394104; = p.P1384S on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); catalogued as rs926916236; called by muse, mutect2, varscan2
- GCH1 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 113/295 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as rs1296731359; called by muse, mutect2, varscan2
- GGTLC2 | c.306G>A p.G102= | Splice Region (SNP) | VAF 245/915 reads (27%) | catalogued as rs1255759814; called by muse, mutect2, varscan2
- GPAT3 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 78/264 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.088); catalogued as rs764066641; called by muse, mutect2, varscan2
- GPAT3 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 80/266 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52357002; called by muse, mutect2, varscan2
- GPAT3 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs752029936, COSV52359055; called by muse, mutect2, varscan2
- GPR139 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 125/339 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs942765597, COSV58501549; called by muse, mutect2, varscan2
- GREB1 | c.2519C>T p.S840F | Missense Mutation (SNP) | VAF 104/323 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as rs766061023; called by muse, mutect2, varscan2
- GRID1 | c.2681C>T p.S894F | Missense Mutation (SNP) | VAF 131/425 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs1395646676, COSV100027161; called by muse, mutect2, varscan2
- HDAC6 | c.3095C>T p.P1032L | Missense Mutation (SNP) | VAF 185/266 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV61927818; called by muse, mutect2, varscan2
- IGFBP6 | c.313C>T p.L105F | Missense Mutation (SNP) | VAF 130/396 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.062); catalogued as COSV56857406; called by muse, mutect2, varscan2
- IGHV3-7 | c.155G>A p.W52* | Nonsense Mutation (SNP) | VAF 122/338 reads (36%) | catalogued as rs782787393; called by mutect2, varscan2
- IGSF22 | c.2681C>G p.A894G (on ENST00000319338; = p.A995G on NM_173588.4) | Missense Mutation (SNP) | VAF 94/287 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); catalogued as COSV55011024, COSV55012184; called by muse, varscan2
- INAVA | c.1837C>T p.R613W | Missense Mutation (SNP) | VAF 147/473 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs1220780880; called by muse, mutect2, varscan2
- ITGB8 | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 149/313 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.235); catalogued as rs751381514, COSV56005590, COSV56015637; called by muse, mutect2, varscan2
- KCNH2 | c.1771G>A p.D591N | Missense Mutation (SNP) | VAF 334/673 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs376319070, COSV51127474; called by muse, mutect2, varscan2
- KIAA1210 | c.2150C>T p.S717F | Missense Mutation (SNP) | VAF 145/205 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99081429; called by muse, mutect2, varscan2
- KIF17 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 178/406 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs868344609; called by muse, varscan2
- KIFC1 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 188/758 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746419470; called by muse, mutect2, varscan2
- KIRREL2 | c.1606C>T p.H536Y | Missense Mutation (SNP) | VAF 115/306 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs958466275; called by muse, mutect2, varscan2
- KLHL25 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 177/457 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.442); catalogued as rs1394378097; called by muse, mutect2, varscan2
- LAPTM5 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 107/291 reads (37%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.526); catalogued as rs1333875769; called by muse, mutect2, varscan2
- LEFTY1 | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 231/478 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV55282782; called by muse, mutect2, varscan2
- LIMS2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 149/403 reads (37%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.003); catalogued as rs1373887077; called by muse, mutect2, varscan2
- LRFN2 | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 166/634 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.037); catalogued as rs1410955542; called by muse, mutect2, varscan2
- LRMDA | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 99/302 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.481); catalogued as rs200703401, COSV65278598; called by muse, mutect2, varscan2
- LRRC14B | c.802C>T p.L268F | Missense Mutation (SNP) | VAF 202/611 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.962); catalogued as rs1335849824; called by muse, mutect2, varscan2
- LRRIQ1 | c.421C>T p.H141Y | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1480413769; called by muse, mutect2, varscan2
- M1AP | c.922C>T p.Q308* | Nonsense Mutation (SNP) | VAF 108/285 reads (38%) | catalogued as COSV51845497; called by muse, mutect2, varscan2
- MAGEL2 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 262/781 reads (34%) | SIFT deleterious, low confidence (0.03); catalogued as rs756716697, COSV58568574, COSV58568736; called by muse, mutect2, varscan2
- MASP2 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 87/235 reads (37%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs762811177, COSV99534477; called by muse, mutect2, varscan2
- MIOX | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 331/621 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs766169332, COSV99326821; called by muse, mutect2, varscan2
- MROH2B | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 138/385 reads (36%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.998); catalogued as COSV68180631; called by muse, mutect2, varscan2
- MTBP | c.2132C>T p.S711L | Missense Mutation (SNP) | VAF 111/288 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200198532; called by muse, mutect2, varscan2
- MTUS2 | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 137/413 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as rs766265965, COSV70916060; called by muse, mutect2, varscan2
- MUC16 | c.27067C>T p.P9023S | Missense Mutation (SNP) | VAF 155/475 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.196); catalogued as COSV101200039; called by muse, mutect2, varscan2
- MUC16 | c.3655C>T p.P1219S | Missense Mutation (SNP) | VAF 140/406 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.763); catalogued as rs769830116, COSV67454358; called by muse, mutect2, varscan2
- MUSK | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 122/349 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs542900379, COSV51885576; called by muse, mutect2, varscan2
- MYO7B | c.2222G>A p.G741E | Missense Mutation (SNP) | VAF 86/307 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286954561; called by muse, mutect2, varscan2
- MYT1L | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 119/322 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV67708208, COSV67722339; called by muse, mutect2, varscan2
- NAP1L1 | c.1047T>A p.D349E | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.935); catalogued as COSV99673941; called by muse, mutect2
- NCAPD3 | c.1218C>T p.I406= | Splice Region (SNP) | VAF 47/147 reads (32%) | catalogued as rs776498251; called by muse, mutect2, varscan2
- NCBP3 | c.1168A>G p.R390G | Missense Mutation (SNP) | VAF 154/422 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs368863088; called by muse, mutect2, varscan2
- NEU1 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 145/501 reads (29%) | catalogued as COSV57665632; called by muse, mutect2, varscan2
- NLRP4 | c.1072G>A p.G358R | Missense Mutation (SNP) | VAF 146/373 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs145150483, COSV56715072; called by muse, mutect2, varscan2
- NOS1AP | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 138/466 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.148); catalogued as rs780159734; called by muse, mutect2, varscan2
- OLAH | c.736G>A p.E246K (on ENST00000378228 / NM_001039702.3; = p.E299K on NM_018324.3) | Missense Mutation (SNP) | VAF 111/341 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as rs1343008369, COSV62252277; called by muse, mutect2, varscan2
- OPCML | c.833T>C p.M278T | Missense Mutation (SNP) | VAF 103/305 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs145413900; called by muse, mutect2, varscan2
- OPRD1 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 200/664 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.101); catalogued as COSV52384031; called by muse, mutect2, varscan2
- OR10A4 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 93/292 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV65841696, COSV65841802; called by muse, mutect2, varscan2
- OR10A5 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 122/319 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.11); catalogued as rs753201880; called by muse, mutect2, varscan2
- OR2T2 | c.9G>A p.M3I | Missense Mutation (SNP) | VAF 163/726 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.116); catalogued as COSV100737803, COSV61617916; called by muse, mutect2, varscan2
- OR56B1 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 131/367 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.344); catalogued as rs762918207, COSV57724030; called by muse, mutect2, varscan2
- OR5M10 | c.912G>A p.M304I | Missense Mutation (SNP) | VAF 64/229 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV73242366; called by muse, mutect2
- OR7G1 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 150/411 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); catalogued as rs769414989, COSV53316818; called by muse, mutect2, varscan2
- OR8A1 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 133/298 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.07); catalogued as COSV52510217, COSV52510454; called by muse, mutect2, varscan2
- OR8B4 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 111/281 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV62069509; called by muse, mutect2, varscan2
- PAAF1 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 87/306 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs774829882; called by muse, mutect2, varscan2
- PAPPA2 | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 165/536 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); catalogued as rs575778188, COSV100866390, COSV62776538; called by muse, mutect2, varscan2
- PER1 | c.2273C>T p.P758L | Missense Mutation (SNP) | VAF 190/563 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV100424966; called by muse, mutect2
- PHKA1 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 79/111 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782361698; called by muse, mutect2, varscan2
- PI4KA | c.5402C>T p.A1801V | Missense Mutation (SNP) | VAF 82/383 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55410277; called by muse, mutect2, varscan2
- PIK3CG | c.2252C>T p.S751L | Missense Mutation (SNP) | VAF 83/386 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs528601604, COSV100782915, COSV63247529; called by muse, mutect2, varscan2
- PINK1 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 104/310 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs376323248; called by muse, mutect2, varscan2
- PLEKHG1 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 113/330 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs963132139, COSV62048347, COSV62048905; called by muse, mutect2, varscan2
- PPP4R3C | c.2101G>A p.D701N | Missense Mutation (SNP) | VAF 112/150 reads (75%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.936); catalogued as COSV69080890; called by muse, mutect2, varscan2
- PRDM9 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 72/226 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV57005401; called by muse, mutect2, varscan2
- PRLR | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 147/412 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV99184420; called by muse, mutect2, varscan2
- PRSS58 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 276/522 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.091); catalogued as COSV73488856; called by muse, mutect2, varscan2
- PSG4 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 171/461 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs769047324, COSV54938968, COSV99737771; called by muse, mutect2, varscan2
- PSG6 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 87/306 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as COSV51835600; called by muse, mutect2, varscan2
- PTPN20 | c.918C>T p.S306= | Splice Region (SNP) | VAF 17/34 reads (50%) | catalogued as rs1240630047; called by mutect2, varscan2
- PTPRB | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 140/405 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.662); catalogued as rs768944578, COSV54236974; called by muse, mutect2, varscan2
- RALGPS1 | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 68/204 reads (33%) | catalogued as rs781621744, COSV52231820; called by muse, mutect2, varscan2
- RBM20 | c.3271G>A p.E1091K | Missense Mutation (SNP) | VAF 146/452 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as rs565524160, COSV65702827; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RFPL1 | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 388/712 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1344198314; called by muse, mutect2, varscan2
- RNF123 | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 172/494 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.197); catalogued as rs370368339; called by muse, mutect2, varscan2
- RNF123 | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 157/462 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV59689027; called by muse, varscan2
- RUNX1 | c.1169C>T p.S390F (on ENST00000344691 / NM_001001890.3; = p.S417F on NM_001754.5) | Missense Mutation (SNP) | VAF 105/254 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55875511; called by muse, mutect2, varscan2
- SBF2 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 104/256 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as rs781039677; called by muse, mutect2, varscan2
- SCGN | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs773596671; called by muse, mutect2, varscan2
- SCN7A | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV101313353; called by muse, mutect2, varscan2
- SEMA4F | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 108/261 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1243999809; called by muse, mutect2, varscan2
- SEMG1 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 96/312 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs750800652, COSV54871925; called by muse, mutect2, varscan2
- SERPINB3 | c.1121G>A p.R374K | Missense Mutation (SNP) | VAF 110/319 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.072); catalogued as rs141091024; called by muse, mutect2
- SETDB1 | c.2003G>A p.R668Q | Missense Mutation (SNP) | VAF 187/490 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs199613890, COSV54984269; called by muse, mutect2, varscan2
- SIRT2 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 116/337 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1409624182, COSV50875570; called by muse, mutect2, varscan2
- SLC15A1 | c.945C>T p.I315= | Splice Region (SNP) | VAF 114/365 reads (31%) | catalogued as rs1314211245, COSV64733668; called by muse, mutect2, varscan2
- SLC3A1 | c.1442G>A p.G481E | Missense Mutation (SNP) | VAF 109/274 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CP015817; called by muse, mutect2, varscan2
- SLC4A10 | c.1405G>A p.G469R (on ENST00000446997 / NM_001354461.2; = p.G439R on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 116/362 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.14); catalogued as rs755119585, COSV99763186; called by muse, varscan2
- SLC4A5 | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 242/697 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.366); catalogued as rs1487439862; called by muse, mutect2, varscan2
- SLC8A1 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 112/312 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs866533352, COSV60493498; called by muse, mutect2, varscan2
- SLC8A3 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 164/380 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1263761027; called by muse, mutect2, varscan2
- SLC9C2 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV62943997; called by muse, mutect2, varscan2
- SLITRK6 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 100/289 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.058); catalogued as COSV101233153; called by muse, mutect2, varscan2
- SP2 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 256/587 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.416); catalogued as rs749430104; called by muse, mutect2, varscan2
- SPON1 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 145/374 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV59961582; called by muse, mutect2, varscan2
- SRL | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 112/285 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1346423152, COSV101281374; called by muse, mutect2, varscan2
- STAB1 | c.4078G>A p.E1360K | Missense Mutation (SNP) | VAF 166/457 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1407634558, COSV58731529; called by muse, mutect2, varscan2
- SVEP1 | c.5505G>A p.W1835* | Nonsense Mutation (SNP) | VAF 70/199 reads (35%) | catalogued as COSV52839612; called by muse, mutect2, varscan2
- SVEP1 | c.2668G>A p.E890K | Missense Mutation (SNP) | VAF 143/384 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs749599234; called by muse, mutect2, varscan2
- SYNE2 | c.4013_4014del p.S1338Cfs*2 | Frame Shift Del (DEL) | VAF 136/430 reads (32%) | catalogued as rs1267331874; called by pindel, varscan2
- SYT2 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 233/530 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99053045; called by muse, varscan2
- TACC2 | c.5903C>T p.P1968L (on ENST00000334433; = p.P46L on NM_006997.4) | Missense Mutation (SNP) | VAF 127/354 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1455549169; called by muse, mutect2, varscan2
- TENM2 | c.3022G>A p.V1008M (on ENST00000518659 / NM_001122679.2; = p.V776M on NM_001080428.3) | Missense Mutation (SNP) | VAF 127/462 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs765917741, COSV101319506; called by muse, mutect2, varscan2
- THSD7A | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 160/600 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.318); catalogued as rs1386222707; called by muse, mutect2, varscan2
- THSD7B | c.1147C>T p.L383F | Missense Mutation (SNP) | VAF 116/359 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.583); catalogued as rs936570414; called by muse, mutect2, varscan2
- TMEM26 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 140/370 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs759395883; called by muse, varscan2
- TMPRSS11B | c.687G>A p.K229= | Splice Region (SNP) | VAF 20/73 reads (27%) | catalogued as COSV60291749; called by muse, mutect2
- TMPRSS2 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 194/600 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV59823528; called by muse, mutect2, varscan2
- TRAPPC9 | c.2057C>T p.S686F | Missense Mutation (SNP) | VAF 110/322 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as rs765364454; called by muse, mutect2, varscan2
- TRAV18 | c.206G>A p.S69N | Missense Mutation (SNP) | VAF 125/329 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs781594440; called by muse, mutect2, varscan2
- TRERF1 | c.2515C>T p.P839S | Missense Mutation (SNP) | VAF 124/470 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.313); catalogued as rs1014385930; called by muse, mutect2, varscan2
- TRPM2 | c.3758C>T p.T1253M | Missense Mutation (SNP) | VAF 126/405 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs775450744; called by muse, mutect2, varscan2
- TRPM2 | c.3965G>A p.G1322E | Missense Mutation (SNP) | VAF 125/377 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55978428; called by muse, mutect2, varscan2
- TTN | c.75053G>A p.G25018E (on ENST00000591111; = p.G17594E on NM_003319.4) | Missense Mutation (SNP) | VAF 103/317 reads (32%) | PolyPhen probably damaging (1); catalogued as COSV60333610; called by muse, mutect2, varscan2
- TTN | c.58735G>A p.G19579R (on ENST00000591111; = p.G12155R on NM_003319.4) | Missense Mutation (SNP) | VAF 121/385 reads (31%) | PolyPhen probably damaging (1); catalogued as COSV59959160; called by muse, mutect2, varscan2
- TTN | c.43216G>A p.E14406K (on ENST00000591111; = p.E6982K on NM_003319.4) | Missense Mutation (SNP) | VAF 85/254 reads (33%) | PolyPhen possibly damaging (0.84); catalogued as COSV59863108; called by muse, mutect2, varscan2
- TTN | c.42589C>T p.R14197* (on ENST00000591111; = p.R6773* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 162/414 reads (39%) | catalogued as rs762271078, COSV59941796; called by muse, mutect2, varscan2
- UNC45B | c.2260C>T p.R754W | Missense Mutation (SNP) | VAF 67/239 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779897509; called by muse, mutect2, varscan2
- UNC5C | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 99/277 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV71661126; called by muse, mutect2, varscan2
- USH2A | c.12602G>A p.G4201E | Missense Mutation (SNP) | VAF 170/435 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.561); catalogued as COSV100235319; called by muse, varscan2
- VPS35L | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 127/350 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as rs150962264; called by muse, mutect2, varscan2
- VSIG10L2 | c.2085G>A p.A695= | Splice Region (SNP) | VAF 49/233 reads (21%) | catalogued as rs573689856; called by muse, mutect2, varscan2
- ZAN | c.4168G>A p.G1390R | Missense Mutation (SNP) | VAF 166/649 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1167668223; called by muse, mutect2
- ZBED6 | c.983T>C p.V328A | Missense Mutation (SNP) | VAF 162/411 reads (39%) | SIFT tolerated (0.91); PolyPhen benign (0.017); catalogued as rs1035979106; called by muse, mutect2, varscan2
- ZBED9 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 89/332 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.979); catalogued as COSV71729251; called by muse, mutect2, varscan2
- ZBTB21 | c.2932C>T p.P978S | Missense Mutation (SNP) | VAF 115/363 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs140576114; called by muse, mutect2, varscan2
- ZNF226 | c.883C>T p.L295F | Missense Mutation (SNP) | VAF 113/337 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56197680; called by muse, mutect2, varscan2
- ZNF423 | c.2132C>T p.S711L (on ENST00000563137 / NM_001379286.1; = p.S703L on NM_015069.4) | Missense Mutation (SNP) | VAF 157/427 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs144284315; called by muse, mutect2, varscan2
- ZNF713 | c.562C>T p.P188S (on ENST00000633730 / NM_001366796.2; = p.P201S on NM_182633.3) | Missense Mutation (SNP) | VAF 210/426 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs745778390, COSV70057286; called by muse, mutect2, varscan2
- ABCC6 | c.2234C>T p.S745L | Missense Mutation (SNP) | VAF 105/301 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ACOX2 | c.1955G>A p.W652* | Nonsense Mutation (SNP) | VAF 118/328 reads (36%) | called by muse, mutect2, varscan2
- ACOX3 | c.761A>G p.N254S | Missense Mutation (SNP) | VAF 133/353 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ACR | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 199/380 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.36); called by muse, mutect2
- ADAM19 | c.2405C>T p.S802F | Missense Mutation (SNP) | VAF 161/262 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ADAMTS10 | c.2576C>T p.S859F | Missense Mutation (SNP) | VAF 156/447 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- ADAMTS13 | c.3659C>T p.P1220L | Missense Mutation (SNP) | VAF 138/438 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS15 | c.1553C>T p.S518F | Missense Mutation (SNP) | VAF 133/319 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS20 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 67/197 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ADD3 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 117/324 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ADPRHL1 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 125/355 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- AFM | c.1568C>T p.P523L | Missense Mutation (SNP) | VAF 74/247 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- AIG1 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 157/355 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ALKBH8 | c.1963G>A p.G655R | Missense Mutation (SNP) | VAF 104/239 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AMER3 | c.195C>A p.C65* | Nonsense Mutation (SNP) | VAF 150/508 reads (30%) | called by muse, mutect2, varscan2
- ANKS1A | c.2357A>T p.D786V | Missense Mutation (SNP) | VAF 131/605 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANO2 | c.856G>A p.A286T (on ENST00000356134 / NM_001278597.3; = p.A290T on NM_001278596.3) | Missense Mutation (SNP) | VAF 127/352 reads (36%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOB | c.5764G>A p.E1922K | Missense Mutation (SNP) | VAF 115/371 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- ARHGEF3 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 170/412 reads (41%) | called by muse, mutect2, varscan2
- ARMC5 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 190/483 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATIC | c.1450A>T p.R484* | Nonsense Mutation (SNP) | VAF 128/375 reads (34%) | called by muse, mutect2, varscan2
- ATP2B3 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 75/103 reads (73%) | SIFT tolerated (0.16); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ATRNL1 | c.278G>T p.C93F | Missense Mutation (SNP) | VAF 131/352 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BCR | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 150/584 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BPIFB3 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 109/274 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- C10orf90 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 142/470 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, mutect2
- C11orf87 | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 70/277 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CACNB2 | c.1415C>T p.P472L (on ENST00000324631 / NM_201596.3; = p.P417L on NM_000724.4) | Missense Mutation (SNP) | VAF 160/453 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- CAMSAP1 | c.20G>C p.R7P | Missense Mutation (SNP) | VAF 98/299 reads (33%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CAPN10 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 139/450 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- CDH8 | c.1023+1G>A p.X341_splice | Splice Site (SNP) | VAF 85/202 reads (42%) | called by muse, mutect2, varscan2
- CECR2 | c.1618C>T p.P540S (on ENST00000342247 / NM_001290047.2; = p.P357S on NM_001290046.1) | Missense Mutation (SNP) | VAF 246/486 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- CEP104 | c.437T>C p.V146A | Missense Mutation (SNP) | VAF 104/252 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- CEP131 | c.1552C>T p.P518S (on ENST00000269392 / NM_001319228.2; = p.P515S on NM_014984.4) | Missense Mutation (SNP) | VAF 191/434 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- CFAP58 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 121/332 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CLCN1 | c.1401G>A p.K467= | Splice Region (SNP) | VAF 170/327 reads (52%) | called by muse, mutect2, varscan2
- CLEC20A | c.1151G>A p.G384D | Missense Mutation (SNP) | VAF 107/266 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- CNR2 | c.774G>A p.W258* | Nonsense Mutation (SNP) | VAF 197/461 reads (43%) | called by muse, mutect2, varscan2
- COL28A1 | c.1998G>A p.K666= | Splice Region (SNP) | VAF 210/389 reads (54%) | called by muse, varscan2
- COL4A2 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 87/244 reads (36%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- COL4A6 | c.4364G>A p.G1455E | Missense Mutation (SNP) | VAF 161/204 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL9A1 | c.2650G>A p.G884R | Missense Mutation (SNP) | VAF 163/467 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COPA | c.2851C>T p.Q951* | Nonsense Mutation (SNP) | VAF 117/385 reads (30%) | called by muse, mutect2, varscan2
- CPAMD8 | c.527C>T p.S176F (on ENST00000651564; = p.S129F on NM_015692.5) | Missense Mutation (SNP) | VAF 107/393 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- CSMD1 | c.2468C>T p.S823F (on ENST00000520002; = p.S822F on NM_033225.6) | Missense Mutation (SNP) | VAF 143/354 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSMD3 | c.8227G>A p.G2743S | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUBN | c.7397C>T p.P2466L | Missense Mutation (SNP) | VAF 122/323 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- CXXC4 | c.1095G>A p.W365* | Nonsense Mutation (SNP) | VAF 33/83 reads (40%) | called by muse, mutect2, varscan2
- DDX11 | c.2898G>A p.W966* | Nonsense Mutation (SNP) | VAF 26/138 reads (19%) | called by mutect2, varscan2
- DGKD | c.1588G>A p.E530K (on ENST00000264057 / NM_152879.3; = p.E486K on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 161/393 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DHCR7 | c.41G>A p.S14N | Missense Mutation (SNP) | VAF 135/296 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH11 | c.3339G>A p.M1113I | Missense Mutation (SNP) | VAF 123/439 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DNAH5 | c.5912G>A p.G1971E | Missense Mutation (SNP) | VAF 94/333 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DNAH8 | c.4063A>C p.K1355Q | Missense Mutation (SNP) | VAF 56/283 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- DNTTIP2 | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 73/182 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- DQX1 | c.2059C>T p.L687F | Missense Mutation (SNP) | VAF 171/433 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DYNC2H1 | c.7501C>T p.Q2501* | Nonsense Mutation (SNP) | VAF 90/218 reads (41%) | called by muse, mutect2, varscan2
- EFCAB14 | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 107/401 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ENPEP | c.2240C>T p.S747F | Missense Mutation (SNP) | VAF 87/265 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- FAM111A | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 120/331 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- FAM185A | c.457G>C p.D153H | Missense Mutation (SNP) | VAF 130/259 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- FAM209A | c.481A>T p.I161F | Missense Mutation (SNP) | VAF 111/323 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FOXJ2 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 168/472 reads (36%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FREM3 | c.3419C>T p.S1140F | Missense Mutation (SNP) | VAF 136/384 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GAGE2E | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 23/323 reads (7%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GLP1R | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 129/511 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- GRHL3 | c.424C>T p.P142S (on ENST00000350501 / NM_198174.3; = p.P147S on NM_021180.3) | Missense Mutation (SNP) | VAF 158/370 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GUCY2F | c.3224C>A p.P1075Q | Missense Mutation (SNP) | VAF 131/195 reads (67%) | SIFT tolerated (0.17); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HDAC3 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 113/223 reads (51%) | called by muse, mutect2, varscan2
- HIRA | c.2381C>T p.A794V | Missense Mutation (SNP) | VAF 84/332 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HLA-DQA2 | c.490C>T p.L164F | Missense Mutation (SNP) | VAF 149/1352 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- HMCN2 | c.14417C>T p.T4806I | Missense Mutation (SNP) | VAF 130/400 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HPSE | c.1197T>G p.D399E | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGSF23 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 91/275 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGSF23 | c.560G>A p.R187K | Missense Mutation (SNP) | VAF 132/348 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.16); called by muse, varscan2
- IL17C | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 217/369 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ITGA4 | c.1062G>A p.M354I | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ITGA7 | c.1114G>A p.D372N (on ENST00000555728; = p.D328N on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/279 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- ITIH2 | c.2174G>A p.G725E | Missense Mutation (SNP) | VAF 93/261 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JADE3 | c.1943G>C p.G648A | Missense Mutation (SNP) | VAF 228/299 reads (76%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KANSL1 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 189/560 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- KCNB2 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 181/417 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- KCNT2 | c.3191G>A p.G1064D | Missense Mutation (SNP) | VAF 124/328 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- KIAA1217 | c.3328C>T p.P1110S | Missense Mutation (SNP) | VAF 157/452 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KMT2C | c.4903A>G p.S1635G | Missense Mutation (SNP) | VAF 122/504 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- KRT6B | c.1481C>T p.S494F | Missense Mutation (SNP) | VAF 133/402 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- KSR2 | c.2818C>T p.H940Y | Missense Mutation (SNP) | VAF 116/301 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LEFTY1 | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 229/477 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- LHX8 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 77/229 reads (34%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- LMO7 | c.4082A>G p.E1361G (on ENST00000357063; = p.E1042G on NM_005358.5) | Missense Mutation (SNP) | VAF 140/377 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- LPA | c.3028G>A p.E1010K | Missense Mutation (SNP) | VAF 108/316 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MALRD1 | c.3297A>T p.K1099N | Missense Mutation (SNP) | VAF 102/265 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- MAS1L | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 203/844 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MICB | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 146/575 reads (25%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); called by muse, varscan2
- MRGPRE | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 157/462 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MYH14 | c.5437G>A p.E1813K | Missense Mutation (SNP) | VAF 183/473 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- MYT1 | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 136/433 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- NANS | c.446A>G p.K149R | Missense Mutation (SNP) | VAF 83/217 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NCK2 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 86/219 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEURL1 | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 164/464 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP3 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 166/533 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- NOVA2 | c.1118G>A p.G373E | Missense Mutation (SNP) | VAF 82/252 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NPAS4 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 146/374 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NWD1 | c.3976G>A p.D1326N | Missense Mutation (SNP) | VAF 171/464 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- OR1I1 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 135/378 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- OR2A14 | c.266G>A p.S89N | Missense Mutation (SNP) | VAF 172/350 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5BS1P | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 118/318 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- OR9G4 | c.277T>A p.S93T | Missense Mutation (SNP) | VAF 191/555 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PABPN1L | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 114/212 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PER3 | c.2327C>T p.S776F | Missense Mutation (SNP) | VAF 169/598 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PITX3 | c.869A>G p.N290S | Missense Mutation (SNP) | VAF 182/457 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PKHD1 | c.5128C>T p.P1710S | Missense Mutation (SNP) | VAF 136/341 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- PLIN4 | c.4006G>A p.G1336S (on ENST00000301286; = p.G1351S on NM_001367868.2) | Missense Mutation (SNP) | VAF 162/451 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PRAMEF1 | c.1388C>T p.S463L | Missense Mutation (SNP) | VAF 108/506 reads (21%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); called by muse, varscan2
- PRKAA2 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 136/337 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- PRUNE2 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 133/379 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PTPRM | c.3051G>C p.E1017D | Missense Mutation (SNP) | VAF 13/281 reads (5%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.887); called by muse, mutect2
- PTPRQ | c.6373G>A p.E2125K (on ENST00000616559; = p.E2092K on NM_001145026.2) | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- RBM45 | c.1310G>A p.R437K (on ENST00000616198 / NM_001365579.1; = p.R435K on NM_152945.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/240 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- REELD1 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 88/297 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RNF175 | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 101/271 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RP1 | c.2927C>T p.T976I | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- RP1L1 | c.3148G>A p.G1050R | Missense Mutation (SNP) | VAF 162/426 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RPGR | c.1685A>T p.H562L | Missense Mutation (SNP) | VAF 126/179 reads (70%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA3E | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 72/402 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.7); called by muse, mutect2
- SLC26A9 | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 180/450 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC4A10 | c.1030C>T p.R344* (on ENST00000446997 / NM_001354461.2; = p.R314* on NM_022058.4 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 143/410 reads (35%) | called by muse, mutect2, varscan2
- SLC7A13 | c.1109G>A p.W370* | Nonsense Mutation (SNP) | VAF 36/115 reads (31%) | called by muse, mutect2, varscan2
- SLC7A13 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 98/307 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLFN12L | c.447G>A p.M149I (on ENST00000260908 / NM_001363830.1; = p.M167I on NM_001195790.1) | Missense Mutation (SNP) | VAF 148/419 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA22 | c.86G>A p.R29K | Missense Mutation (SNP) | VAF 69/219 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- SRSF8 | c.428G>A p.R143K | Missense Mutation (SNP) | VAF 150/368 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- SSTR1 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 139/392 reads (35%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ST14 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 118/327 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- STAB2 | c.2227G>A p.G743S | Missense Mutation (SNP) | VAF 78/247 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- STAT1 | c.1213C>T p.R405W | Missense Mutation (SNP) | VAF 120/307 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM3 | c.7864G>A p.E2622K | Missense Mutation (SNP) | VAF 86/266 reads (32%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TGFBRAP1 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 168/497 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TIAM2 | c.1605G>A p.W535* | Nonsense Mutation (SNP) | VAF 95/258 reads (37%) | called by muse, mutect2, varscan2
- TNFSF9 | c.17A>G p.D6G | Missense Mutation (SNP) | VAF 108/298 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.129); called by muse, varscan2
- TRIM38 | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 158/568 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRIM64B | c.1294C>T p.P432S | Missense Mutation (SNP) | VAF 63/441 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- TRPM6 | c.5422C>T p.P1808S | Missense Mutation (SNP) | VAF 157/389 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTC13 | c.2491C>T p.L831F | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- TTC39B | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 88/247 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- TTN | c.30124G>A p.E10042K (on ENST00000591111; = p.E9115K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/146 reads (50%) | PolyPhen benign (0.075); called by muse, mutect2, varscan2
- UHRF1BP1 | c.1008T>G p.C336W | Missense Mutation (SNP) | VAF 102/386 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UPB1 | c.276G>A p.Q92= | Splice Region (SNP) | VAF 82/353 reads (23%) | called by muse, mutect2, varscan2
- UTP20 | c.3601C>T p.P1201S | Missense Mutation (SNP) | VAF 62/211 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- VCPIP1 | c.3341C>T p.S1114F | Missense Mutation (SNP) | VAF 135/383 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- WDR87 | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 112/310 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZAN | c.3437G>A p.G1146E | Missense Mutation (SNP) | VAF 85/364 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ZBED9 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 120/567 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZBTB6 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 90/264 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF217 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 106/289 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ZNF469 | c.10255C>T p.P3419S (on ENST00000437464; = p.P3447S on NM_001367624.2) | Missense Mutation (SNP) | VAF 222/349 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, varscan2
- ZNF658 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by mutect2, varscan2
- ABI3BP | c.1185G>A p.E395= | Silent (SNP) | VAF 74/232 reads (32%) | catalogued as rs1331986272; called by muse, varscan2
- ACAD9 | c.1686C>T p.D562= | Silent (SNP) | VAF 93/307 reads (30%) | catalogued as COSV100459287; called by muse, mutect2, varscan2
- ADAM29 | c.2028C>T p.F676= | Silent (SNP) | VAF 73/289 reads (25%) | called by muse, mutect2, varscan2
- ADAMTS13 | c.3660C>T p.P1220= | Silent (SNP) | VAF 137/434 reads (32%) | called by muse, mutect2, varscan2
- ADAMTS4 | c.102G>A p.L34= | Silent (SNP) | VAF 292/716 reads (41%) | catalogued as COSV63488807; called by muse, mutect2, varscan2
- ADCY8 | c.1320C>T p.N440= | Silent (SNP) | VAF 115/297 reads (39%) | catalogued as rs77053582; called by muse, mutect2, varscan2
- ALPK3 | c.588C>T p.I196= | Silent (SNP) | VAF 173/436 reads (40%) | catalogued as COSV51941110; called by muse, varscan2
- ANK3 | c.882C>T p.I294= | Silent (SNP) | VAF 58/158 reads (37%) | catalogued as rs756124426, COSV55044592; called by muse, mutect2, varscan2
- ARAP1 | c.2145C>T p.F715= (on ENST00000393609 / NM_001040118.2; = p.F470= on NM_015242.4) | Silent (SNP) | VAF 86/294 reads (29%) | called by muse, mutect2, varscan2
- ARAP2 | c.1923C>T p.D641= | Silent (SNP) | VAF 43/103 reads (42%) | called by muse, mutect2, varscan2
- ARMC5 | c.1989C>T p.F663= | Silent (SNP) | VAF 173/461 reads (38%) | catalogued as COSV51654733; called by muse, mutect2, varscan2
- ASL | c.543C>T p.T181= | Silent (SNP) | VAF 132/462 reads (29%) | called by muse, mutect2, varscan2
- ASPHD2 | c.486C>T p.I162= | Silent (SNP) | VAF 285/543 reads (52%) | called by muse, mutect2, varscan2
- ATP8B4 | c.2868C>T p.F956= | Silent (SNP) | VAF 106/366 reads (29%) | catalogued as rs150358448, COSV52721696; called by muse, mutect2, varscan2
- AVEN | c.840C>T p.D280= | Silent (SNP) | VAF 139/378 reads (37%) | called by muse, mutect2, varscan2
- BCL9L | c.4170C>T p.S1390= | Silent (SNP) | VAF 128/492 reads (26%) | catalogued as rs560735167; called by muse, mutect2
- BCL9L | c.2274G>A p.L758= | Silent (SNP) | VAF 178/406 reads (44%) | catalogued as COSV52686664; called by muse, mutect2, varscan2
- BPIFA1 | c.519C>T p.I173= | Silent (SNP) | VAF 155/423 reads (37%) | catalogued as COSV100845664; called by muse, mutect2, varscan2
- CACNA1G | c.3861C>T p.F1287= | Silent (SNP) | VAF 139/431 reads (32%) | catalogued as COSV61735483; called by muse, mutect2, varscan2
- CACNA1H | c.6846G>A p.L2282= | Silent (SNP) | VAF 187/472 reads (40%) | catalogued as rs58394025; called by muse, mutect2, varscan2
- CACNA1S | c.4284G>A p.R1428= | Silent (SNP) | VAF 158/484 reads (33%) | called by muse, mutect2, varscan2
- CATSPERB | c.1134G>A p.R378= | Silent (SNP) | VAF 100/229 reads (44%) | catalogued as rs267604090, COSV56428558; called by muse, mutect2, varscan2
- CCDC185 | c.1011G>A p.K337= | Silent (SNP) | VAF 236/734 reads (32%) | called by muse, mutect2
- CDH13 | c.1629C>T p.S543= | Silent (SNP) | VAF 106/326 reads (33%) | catalogued as COSV51872574; called by muse, mutect2, varscan2
- CELF3 | c.822G>A p.P274= | Silent (SNP) | VAF 241/567 reads (43%) | catalogued as rs753313302; called by muse, mutect2, varscan2
- CEP89 | c.1659G>T p.L553= | Silent (SNP) | VAF 124/390 reads (32%) | called by muse, mutect2, varscan2
- CFAP251 | c.2013G>A p.G671= | Silent (SNP) | VAF 112/284 reads (39%) | called by muse, mutect2, varscan2
- CLDND2 | c.21C>T p.L7= | Silent (SNP) | VAF 110/338 reads (33%) | called by muse, mutect2, varscan2
- CMYA5 | c.10203C>T p.I3401= | Silent (SNP) | VAF 136/350 reads (39%) | catalogued as COSV71408149; called by muse, mutect2, varscan2
- COL24A1 | c.2454G>A p.L818= | Silent (SNP) | VAF 56/186 reads (30%) | called by muse, mutect2, varscan2
- COL7A1 | c.5565G>A p.R1855= | Silent (SNP) | VAF 171/413 reads (41%) | called by muse, mutect2, varscan2
- CUX2 | c.2355C>T p.F785= | Silent (SNP) | VAF 170/542 reads (31%) | catalogued as COSV55637281; called by muse, varscan2
- CXCR5 | c.435G>A p.V145= | Silent (SNP) | VAF 154/360 reads (43%) | called by muse, mutect2, varscan2
- CYP2C19 | c.846C>T p.F282= | Silent (SNP) | VAF 83/257 reads (32%) | catalogued as COSV64907852, COSV64908199; called by muse, mutect2, varscan2
- DCD | c.93G>A p.G31= | Silent (SNP) | VAF 132/360 reads (37%) | called by muse, mutect2, varscan2
- DCTN1 | c.3693C>T p.F1231= | Silent (SNP) | VAF 102/227 reads (45%) | catalogued as COSV100721128; called by muse, mutect2, varscan2
- DDX3X | c.132C>T p.N44= (on ENST00000399959; = p.N45= on NM_001356.5) | Silent (SNP) | VAF 29/42 reads (69%) | called by muse, mutect2, varscan2
- DMBX1 | c.189T>G p.R63= | Silent (SNP) | VAF 119/327 reads (36%) | called by muse, mutect2, varscan2
- DNAH11 | c.11427A>T p.R3809= | Silent (SNP) | VAF 43/179 reads (24%) | called by muse, mutect2, varscan2
- DNAH7 | c.5943G>A p.G1981= | Silent (SNP) | VAF 56/162 reads (35%) | catalogued as rs267599140; called by muse, mutect2, varscan2
- DNHD1 | c.2223G>A p.K741= | Silent (SNP) | VAF 157/391 reads (40%) | called by muse, mutect2, varscan2
- DNM2 | c.420C>T p.I140= | Silent (SNP) | VAF 119/302 reads (39%) | catalogued as COSV58957234; called by muse, mutect2, varscan2
- DSE | c.1242C>T p.F414= | Silent (SNP) | VAF 131/333 reads (39%) | catalogued as COSV59063190; called by muse, mutect2, varscan2
- DSG3 | c.2999G>A p.*1000= | Silent (SNP) | VAF 57/197 reads (29%) | called by muse, mutect2, varscan2
- DTX1 | c.1521C>T p.I507= | Silent (SNP) | VAF 143/370 reads (39%) | catalogued as rs777051186, COSV55656228; called by muse, mutect2, varscan2
- ELMO1 | c.297C>T p.A99= | Silent (SNP) | VAF 152/543 reads (28%) | catalogued as rs1406433888, COSV100164485; called by muse, mutect2, varscan2
- EPHA6 | c.747G>A p.E249= | Silent (SNP) | VAF 117/378 reads (31%) | called by muse, mutect2, varscan2
- EPHA7 | c.675C>T p.S225= | Silent (SNP) | VAF 116/332 reads (35%) | catalogued as COSV100992340; called by muse, mutect2, varscan2
- EPYC | c.585G>A p.E195= | Silent (SNP) | VAF 108/319 reads (34%) | catalogued as rs757772864; called by muse, mutect2, varscan2
- EZR | c.1425C>T p.P475= | Silent (SNP) | VAF 234/535 reads (44%) | called by muse, mutect2, varscan2
- FAM228B | c.765C>T p.S255= | Silent (SNP) | VAF 76/241 reads (32%) | called by muse, mutect2, varscan2
- FAM71A | c.1263G>A p.K421= | Silent (SNP) | VAF 211/663 reads (32%) | called by muse, mutect2, varscan2
- FAM71E2 | c.2250G>A p.G750= | Silent (SNP) | VAF 127/370 reads (34%) | catalogued as rs780065200; called by muse, mutect2, varscan2
- FBN3 | c.720C>T p.I240= | Silent (SNP) | VAF 164/433 reads (38%) | called by muse, mutect2, varscan2
- FGD5 | c.2259C>T p.F753= | Silent (SNP) | VAF 121/384 reads (32%) | called by muse, mutect2, varscan2
- FREM1 | c.2094G>A p.G698= | Silent (SNP) | VAF 65/225 reads (29%) | catalogued as rs1394065861; called by muse, mutect2, varscan2
- FSHR | c.1620G>A p.L540= | Silent (SNP) | VAF 196/481 reads (41%) | called by muse, mutect2, varscan2
- FZD5 | c.819C>T p.F273= | Silent (SNP) | VAF 166/457 reads (36%) | called by muse, mutect2, varscan2
- GASK1A | c.450C>T p.D150= | Silent (SNP) | VAF 147/446 reads (33%) | catalogued as rs1263509185; called by muse, mutect2, varscan2
- HDAC9 | c.471G>A p.T157= | Silent (SNP) | VAF 72/338 reads (21%) | catalogued as rs749900740, COSV67783036; called by muse, mutect2, varscan2
- HMCN2 | c.14418C>T p.T4806= | Silent (SNP) | VAF 133/401 reads (33%) | called by muse, mutect2, varscan2
- HMGCS2 | c.219G>A p.L73= | Silent (SNP) | VAF 156/376 reads (41%) | catalogued as COSV65568429; called by muse, mutect2, varscan2
- HPCA | c.96G>A p.K32= | Silent (SNP) | VAF 133/360 reads (37%) | called by muse, mutect2, varscan2
- IGFBP6 | c.312C>T p.C104= | Silent (SNP) | VAF 133/396 reads (34%) | called by muse, mutect2, varscan2
- IGHE | c.534C>T p.L178= | Silent (SNP) | VAF 106/314 reads (34%) | called by muse, mutect2, varscan2
- IGHV3-74 | c.168C>T p.V56= | Silent (SNP) | VAF 141/354 reads (40%) | catalogued as rs763363664; called by muse, mutect2, varscan2
- IGKV1-5 | c.18C>T p.P6= | Silent (SNP) | VAF 206/559 reads (37%) | catalogued as rs757539286; called by muse, mutect2, varscan2
- IGSF21 | c.1396C>T p.L466= | Silent (SNP) | VAF 148/396 reads (37%) | called by muse, mutect2, varscan2
- IGSF22 | c.2526C>T p.D842= (on ENST00000319338; = p.D943= on NM_173588.4) | Silent (SNP) | VAF 150/442 reads (34%) | called by muse, varscan2
- IKBKG | c.510G>A p.L170= | Silent (SNP) | VAF 48/156 reads (31%) | called by muse, mutect2, varscan2
- IL20RA | c.1431G>A p.T477= | Silent (SNP) | VAF 187/521 reads (36%) | called by muse, mutect2, varscan2
- INAVA | c.1836C>T p.F612= | Silent (SNP) | VAF 146/472 reads (31%) | called by muse, mutect2, varscan2
- INPP5J | c.2943G>A p.R981= (on ENST00000331075 / NM_001284285.2; = p.R613= on NM_001002837.2) | Silent (SNP) | VAF 198/769 reads (26%) | called by muse, mutect2, varscan2
- ITPK1 | c.990A>C p.T330= | Silent (SNP) | VAF 232/560 reads (41%) | called by muse, varscan2
- JAKMIP1 | c.801G>A p.G267= | Silent (SNP) | VAF 124/353 reads (35%) | called by muse, mutect2, varscan2
- KANK1 | c.996G>A p.L332= | Silent (SNP) | VAF 131/396 reads (33%) | catalogued as rs878995176; called by muse, mutect2, varscan2
- KAT14 | c.1686C>T p.S562= | Silent (SNP) | VAF 92/278 reads (33%) | called by muse, mutect2, varscan2
- KCNH1 | c.723C>T p.F241= | Silent (SNP) | VAF 280/576 reads (49%) | catalogued as COSV55093757, COSV55098654; called by muse, mutect2, varscan2
- KCNH3 | c.2832A>C p.A944= | Silent (SNP) | VAF 173/494 reads (35%) | called by muse, mutect2, varscan2
- KCNN1 | c.252G>A p.G84= | Silent (SNP) | VAF 159/457 reads (35%) | catalogued as COSV55839400; called by muse, mutect2, varscan2
- KCNS3 | c.309C>T p.I103= | Silent (SNP) | VAF 154/423 reads (36%) | catalogued as rs141345709; called by muse, mutect2, varscan2
- KCNT1 | c.3000C>T p.I1000= (on ENST00000488444; = p.I1019= on NM_020822.3) | Silent (SNP) | VAF 113/293 reads (39%) | catalogued as COSV53699793; called by muse, mutect2, varscan2
- KIAA1549 | c.384G>A p.Q128= | Silent (SNP) | VAF 147/517 reads (28%) | called by muse, mutect2, varscan2
- KRT36 | c.1284C>T p.V428= | Silent (SNP) | VAF 145/450 reads (32%) | catalogued as COSV60204821; called by muse, mutect2, varscan2
- KRT85 | c.312C>T p.L104= | Silent (SNP) | VAF 212/628 reads (34%) | catalogued as COSV57737116; called by muse, mutect2, varscan2
- LGALS9C | c.1071G>A p.*357= | Silent (SNP) | VAF 70/215 reads (33%) | called by muse, mutect2, varscan2
- LOXHD1 | c.6705G>A p.E2235= (on ENST00000642948; = p.E2173= on NM_144612.7) | Silent (SNP) | VAF 134/384 reads (35%) | called by muse, varscan2
- LRFN2 | c.1782C>T p.A594= | Silent (SNP) | VAF 167/645 reads (26%) | catalogued as rs1455482588; called by muse, mutect2, varscan2
- LRRC14B | c.801C>T p.L267= | Silent (SNP) | VAF 205/611 reads (34%) | catalogued as rs775246470; called by muse, mutect2, varscan2
- MAB21L4 | c.201C>T p.A67= | Silent (SNP) | VAF 193/547 reads (35%) | called by muse, mutect2, varscan2
- MEP1A | c.1266T>C p.D422= | Silent (SNP) | VAF 145/370 reads (39%) | catalogued as rs146027704, COSV57921058; called by muse, mutect2, varscan2
- MGAM2 | c.3138T>C p.N1046= | Silent (SNP) | VAF 120/452 reads (27%) | called by muse, mutect2, varscan2
- MUC12 | c.5781C>T p.F1927= (on ENST00000379442; = p.F1784= on NM_001164462.1) | Silent (SNP) | VAF 51/219 reads (23%) | called by muse, mutect2, varscan2
- MUC12 | c.14280C>T p.F4760= (on ENST00000379442; = p.F4617= on NM_001164462.1) | Silent (SNP) | VAF 73/273 reads (27%) | catalogued as rs878876115; called by muse, mutect2, varscan2
- MUC16 | c.20955G>A p.R6985= | Silent (SNP) | VAF 152/386 reads (39%) | called by muse, mutect2, varscan2
- MUC16 | c.10257G>A p.V3419= | Silent (SNP) | VAF 156/441 reads (35%) | called by muse, mutect2, varscan2
- MUC21 | c.1686G>A p.R562= | Silent (SNP) | VAF 128/537 reads (24%) | called by muse, mutect2, varscan2
- MYCT1 | c.306C>T p.P102= | Silent (SNP) | VAF 123/353 reads (35%) | catalogued as COSV65891448; called by muse, mutect2, varscan2
- MYH10 | c.3780G>A p.Q1260= | Silent (SNP) | VAF 185/459 reads (40%) | catalogued as COSV52612400; called by muse, mutect2, varscan2
- MYOCD | c.1023G>A p.L341= | Silent (SNP) | VAF 130/378 reads (34%) | called by muse, mutect2, varscan2
- MYT1L | c.1602C>T p.V534= | Silent (SNP) | VAF 118/321 reads (37%) | called by muse, mutect2, varscan2
- NBEA | c.6261C>T p.G2087= | Silent (SNP) | VAF 79/238 reads (33%) | catalogued as rs1212864774; called by muse, mutect2, varscan2
- NPHS2 | c.111G>A p.G37= | Silent (SNP) | VAF 288/706 reads (41%) | called by muse, mutect2, varscan2
- NT5C1B | c.663G>A p.V221= (on ENST00000359846 / NM_001199086.2; = p.V161= on NM_033253.4) | Silent (SNP) | VAF 174/505 reads (34%) | called by muse, mutect2, varscan2
- NXNL1 | c.621G>A p.G207= | Silent (SNP) | VAF 82/180 reads (46%) | called by muse, mutect2, varscan2
- OCM | c.288G>A p.G96= | Silent (SNP) | VAF 139/301 reads (46%) | catalogued as rs1280452940, COSV99631503; called by muse, mutect2, varscan2
- ONECUT1 | c.1168T>C p.L390= | Silent (SNP) | VAF 156/447 reads (35%) | catalogued as rs781028194; called by muse, mutect2, varscan2
- OR1P1 | c.81C>T p.L27= | Silent (SNP) | VAF 100/279 reads (36%) | called by muse, mutect2, varscan2
- OR2F2 | c.891G>A p.V297= | Silent (SNP) | VAF 88/410 reads (21%) | catalogued as rs1285983321; called by muse, mutect2, varscan2
- OR56A5 | c.193C>T p.L65= | Silent (SNP) | VAF 177/541 reads (33%) | called by muse, mutect2, varscan2
- OR5P3 | c.687C>T p.H229= | Silent (SNP) | VAF 159/480 reads (33%) | catalogued as rs1020927130; called by muse, mutect2, varscan2
- PABPN1L | c.411C>T p.T137= | Silent (SNP) | VAF 115/211 reads (55%) | called by muse, mutect2, varscan2
- PAPPA | c.1833C>T p.S611= | Silent (SNP) | VAF 135/366 reads (37%) | catalogued as COSV60284505; called by muse, mutect2, varscan2
- PARP14 | c.1938C>T p.I646= | Silent (SNP) | VAF 96/285 reads (34%) | called by muse, mutect2, varscan2
- PBX4 | c.204C>T p.I68= | Silent (SNP) | VAF 132/304 reads (43%) | called by muse, mutect2, varscan2
- PDE1C | c.183C>T p.L61= | Silent (SNP) | VAF 109/482 reads (23%) | called by muse, mutect2, varscan2
- PDPR | c.1647C>T p.F549= | Silent (SNP) | VAF 83/524 reads (16%) | called by muse, mutect2, varscan2
- PGLYRP2 | c.375G>A p.L125= | Silent (SNP) | VAF 181/476 reads (38%) | called by muse, mutect2, varscan2
- PKD2 | c.2739G>A p.L913= | Silent (SNP) | VAF 152/374 reads (41%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.12528G>A p.G4176= | Silent (SNP) | VAF 125/335 reads (37%) | called by muse, mutect2, varscan2
- PLEKHA1 | c.1194C>T p.S398= | Silent (SNP) | VAF 86/264 reads (33%) | called by muse, mutect2, varscan2
- PLEKHH1 | c.2724C>T p.R908= | Silent (SNP) | VAF 137/373 reads (37%) | catalogued as rs759832159; called by muse, mutect2, varscan2
- PODN | c.282G>A p.A94= (on ENST00000395871; = p.A46= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 236/586 reads (40%) | catalogued as rs759710132; called by muse, varscan2
- POU2F3 | c.18C>T p.S6= | Silent (SNP) | VAF 88/319 reads (28%) | catalogued as rs755659476; called by muse, mutect2, varscan2
- PRAMEF15 | c.528G>A p.R176= | Silent (SNP) | VAF 90/888 reads (10%) | called by muse, mutect2
- PROC | c.951C>T p.P317= | Silent (SNP) | VAF 168/500 reads (34%) | called by muse, varscan2
- PSD | c.1545C>T p.P515= | Silent (SNP) | VAF 108/331 reads (33%) | catalogued as COSV99192653; called by muse, mutect2, varscan2
- PSD4 | c.318C>T p.P106= | Silent (SNP) | VAF 184/556 reads (33%) | called by muse, mutect2, varscan2
- PSG4 | c.18C>T p.A6= | Silent (SNP) | VAF 128/189 reads (68%) | called by muse, mutect2
- PSMA1 | c.423C>T p.G141= | Silent (SNP) | VAF 52/203 reads (26%) | called by muse, mutect2, varscan2
- PTPRC | c.3483G>A p.K1161= | Silent (SNP) | VAF 109/287 reads (38%) | called by muse, mutect2, varscan2
- PTPRD | c.5145C>T p.I1715= | Silent (SNP) | VAF 62/247 reads (25%) | catalogued as rs779384586, COSV61979579; called by muse, mutect2, varscan2
- RASSF7 | c.783G>A p.L261= | Silent (SNP) | VAF 164/409 reads (40%) | called by muse, varscan2
- RFPL4B | c.282G>A p.R94= | Silent (SNP) | VAF 160/421 reads (38%) | called by muse, mutect2, varscan2
- SCART1 | c.849C>T p.F283= | Silent (SNP) | VAF 191/580 reads (33%) | catalogued as rs1037369387; called by muse, mutect2, varscan2
- SCN5A | c.5460C>T p.A1820= (on ENST00000333535 / NM_198056.3; = p.A1819= on NM_000335.5) | Silent (SNP) | VAF 135/400 reads (34%) | called by muse, mutect2, varscan2
- SEZ6L | c.1725G>A p.G575= | Silent (SNP) | VAF 106/478 reads (22%) | catalogued as rs267606206, COSV50660711; called by muse, mutect2, varscan2
- SIRPB2 | c.357G>A p.R119= | Silent (SNP) | VAF 148/389 reads (38%) | called by muse, mutect2, varscan2
- SLC17A1 | c.1281C>T p.S427= | Silent (SNP) | VAF 78/294 reads (27%) | catalogued as rs372960186, COSV99765866; called by muse, mutect2, varscan2
- SLC22A31 | c.696C>T p.F232= | Silent (SNP) | VAF 96/178 reads (54%) | called by muse, mutect2, varscan2
- SLC35E4 | c.969C>T p.F323= | Silent (SNP) | VAF 142/575 reads (25%) | catalogued as rs1344673219; called by muse, mutect2, varscan2
- SLC7A10 | c.1107C>T p.L369= | Silent (SNP) | VAF 111/319 reads (35%) | catalogued as rs771119472, COSV53505508; called by muse, mutect2, varscan2
- SLC9C2 | c.2716T>C p.L906= | Silent (SNP) | VAF 86/243 reads (35%) | called by muse, mutect2, varscan2
- SLCO3A1 | c.588C>T p.P196= | Silent (SNP) | VAF 139/441 reads (32%) | called by muse, mutect2, varscan2
- SLFN5 | c.2473C>T p.L825= | Silent (SNP) | VAF 137/378 reads (36%) | catalogued as rs774777202; called by muse, mutect2, varscan2
- SOCS4 | c.1164C>T p.S388= | Silent (SNP) | VAF 72/213 reads (34%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.1263C>T p.I421= | Silent (SNP) | VAF 116/309 reads (38%) | called by muse, mutect2, varscan2
- ST8SIA3 | c.921C>T p.T307= | Silent (SNP) | VAF 125/348 reads (36%) | called by muse, mutect2, varscan2
- STYK1 | c.441G>A p.K147= | Silent (SNP) | VAF 66/235 reads (28%) | called by muse, mutect2, varscan2
- SVEP1 | c.2085C>T p.F695= | Silent (SNP) | VAF 91/273 reads (33%) | called by muse, mutect2, varscan2
- SYCN | c.162G>A p.G54= | Silent (SNP) | VAF 221/594 reads (37%) | catalogued as COSV59213092; called by muse, mutect2, varscan2
- TBX18 | c.618G>A p.S206= | Silent (SNP) | VAF 99/292 reads (34%) | catalogued as rs150088516, COSV63736319; called by muse, mutect2, varscan2
- TBXAS1 | c.676C>T p.L226= | Silent (SNP) | VAF 81/334 reads (24%) | called by muse, mutect2, varscan2
- TGFBR1 | c.39C>T p.L13= | Silent (SNP) | VAF 68/192 reads (35%) | called by muse, varscan2
- TMPRSS3 | c.495C>T p.F165= | Silent (SNP) | VAF 98/292 reads (34%) | catalogued as rs746043102; called by muse, mutect2, varscan2
- TNRC18 | c.1248C>T p.S416= | Silent (SNP) | VAF 240/792 reads (30%) | called by muse, mutect2, varscan2
- TOPAZ1 | c.705C>T p.S235= | Silent (SNP) | VAF 60/160 reads (38%) | called by muse, mutect2, varscan2
- TRMT6 | c.942C>T p.H314= | Silent (SNP) | VAF 139/383 reads (36%) | called by muse, mutect2, varscan2
- TRPV6 | c.267C>T p.L89= | Silent (SNP) | VAF 181/362 reads (50%) | called by muse, mutect2, varscan2
- TTC39B | c.1578C>T p.S526= | Silent (SNP) | VAF 88/244 reads (36%) | called by muse, mutect2, varscan2
- TTN | c.63171C>T p.V21057= (on ENST00000591111; = p.V13633= on NM_003319.4) | Silent (SNP) | VAF 98/306 reads (32%) | called by muse, mutect2, varscan2
- TTN | c.47544G>A p.V15848= (on ENST00000591111; = p.V8424= on NM_003319.4) | Silent (SNP) | VAF 122/384 reads (32%) | catalogued as COSV59928319; called by muse, mutect2, varscan2
- TULP2 | c.744G>A p.T248= | Silent (SNP) | VAF 169/481 reads (35%) | catalogued as rs759744411; called by muse, mutect2, varscan2
- WARS1 | c.711C>T p.D237= | Silent (SNP) | VAF 81/229 reads (35%) | called by muse, mutect2, varscan2
- XKR3 | c.1338G>A p.R446= | Silent (SNP) | VAF 44/231 reads (19%) | called by muse, mutect2, varscan2
- ZNF469 | c.4827G>A p.R1609= (on ENST00000437464; = p.R1637= on NM_001367624.2) | Silent (SNP) | VAF 183/335 reads (55%) | called by muse, mutect2, varscan2
- ZNF491 | c.15C>T p.L5= | Silent (SNP) | VAF 85/212 reads (40%) | catalogued as rs751684697; called by muse, mutect2, varscan2
- ZNF567 | c.1158C>T p.I386= (on ENST00000536254 / NM_001322913.1; = p.I355= on NM_152603.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 146/414 reads (35%) | called by muse, mutect2
- ABI3BP | c.1577-8424G>A | Intron (SNP) | VAF 70/201 reads (35%) | called by muse, mutect2, varscan2
- AHDC1 | c.-265C>T | 5'UTR (SNP) | VAF 93/287 reads (32%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73821769 C>T | 5'Flank (SNP) | VAF 69/101 reads (68%) | catalogued as rs748036139; called by muse, mutect2, varscan2
- C2orf68 | c.226+78C>T | Intron (SNP) | VAF 160/529 reads (30%) | called by muse, mutect2, varscan2
- C2orf68 | c.226+77C>G | Intron (SNP) | VAF 164/532 reads (31%) | called by muse, mutect2, varscan2
- C5orf60 | n.33G>A | RNA (SNP) | VAF 49/434 reads (11%) | catalogued as rs1562391297; called by muse, varscan2
- DCDC2 | c.923-47G>A | Intron (SNP) | VAF 313/585 reads (54%) | catalogued as rs765690334; called by muse, mutect2, varscan2
- GRAMD1B | c.256-2574C>T | Intron (SNP) | VAF 167/247 reads (68%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-423G>A | Intron (SNP) | VAF 187/587 reads (32%) | called by muse, mutect2, varscan2
- IGSF22 | c.*505C>G | 3'UTR (SNP) | VAF 122/321 reads (38%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-30699C>T | Intron (SNP) | VAF 49/148 reads (33%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-3317G>A | Intron (SNP) | VAF 65/223 reads (29%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-3316G>A | Intron (SNP) | VAF 66/225 reads (29%) | called by muse, mutect2, varscan2
- KDM4B | c.1115+1008C>T | Intron (SNP) | VAF 93/254 reads (37%) | catalogued as rs1284994460; called by muse, mutect2, varscan2
- MAGEC3 | c.1728+63G>A | Intron (SNP) | VAF 183/263 reads (70%) | catalogued as rs1441959547; called by muse, mutect2, varscan2
- OR5R1 | chr11:56412774 G>A | 3'Flank (SNP) | VAF 85/280 reads (30%) | called by muse, mutect2, varscan2
- P4HB | c.*124C>T | 3'UTR (SNP) | VAF 180/513 reads (35%) | called by muse, mutect2, varscan2
- PLAAT4 | c.387+22C>T | Intron (SNP) | VAF 145/397 reads (37%) | catalogued as rs750052185; called by muse, mutect2, varscan2
- PRKAR2B | c.-181G>A | 5'UTR (SNP) | VAF 124/471 reads (26%) | called by muse, mutect2, varscan2
- PRKAR2B | c.-180G>A | 5'UTR (SNP) | VAF 110/433 reads (25%) | called by muse, varscan2
- PTRH1 | c.96+66C>T | Intron (SNP) | VAF 106/347 reads (31%) | catalogued as rs571135579; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1569-5140C>T | Intron (SNP) | VAF 183/452 reads (40%) | called by muse, mutect2, varscan2
- SEPTIN3 | chr22:41971899 G>A | 5'Flank (SNP) | VAF 124/471 reads (26%) | called by muse, mutect2, varscan2
- ST3GAL3 | c.254+9856G>A | Intron (SNP) | VAF 132/361 reads (37%) | called by muse, mutect2, varscan2
- TTC6 | c.357+1639G>A | Intron (SNP) | VAF 74/219 reads (34%) | called by muse, mutect2, varscan2
- Z99774.2 | chr22:26675474 G>A | 3'Flank (SNP) | VAF 123/437 reads (28%) | called by muse, mutect2, varscan2
- ZNF677 | c.169+1461C>T | Intron (SNP) | VAF 66/218 reads (30%) | called by muse, mutect2, varscan2
